Somatic mutation profile of tumor specimen TCGA-WB-A821-01A (aliquot TCGA-WB-A821-01A-11D-A35I-08) from TCGA case TCGA-WB-A821, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 73.4 years (26,805 days).
Specimen TCGA-WB-A821-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36a19926-0fa0-4043-9173-13460e0bb4f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A821-10A (Blood Derived Normal), aliquot TCGA-WB-A821-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f975009-e5f2-42e8-a97b-82c1a3f2ec10

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 17, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPAS1 | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1513699, COSV55383943, COSV55387430; called by muse, mutect2, varscan2
- GALNTL6 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs1390582620, COSV72489150; called by muse, mutect2, varscan2
- LSM14B | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV53380508; called by muse, mutect2, varscan2
- MYH9 | c.3820A>G p.K1274E | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.347); catalogued as rs776320326; called by muse, mutect2, varscan2
- SLC10A5 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1563597270; called by muse, mutect2
- TAF4 | c.2086G>A p.V696M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs767742516, COSV53344057; called by muse, mutect2
- AZIN1 | c.17A>C p.D6A | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- CEP192 | c.7388T>C p.L2463P | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CFAP91 | c.1105T>G p.S369A | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CYTH2 | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.679); called by muse, mutect2
- DNAH5 | c.12266A>G p.Q4089R | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.094); called by muse, mutect2
- ERC2 | c.588G>C p.L196F | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- GNE | c.226G>A p.V76I (on ENST00000396594 / NM_001128227.3; = p.V45I on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.618); called by muse, mutect2
- GPATCH8 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARN | c.1142A>G p.Y381C | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- PIGS | c.1195A>G p.I399V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- RAI1 | c.3716T>G p.L1239R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNTN3 | c.1584G>T p.L528= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- OIT3 | c.801G>A p.L267= | Silent (SNP) | VAF 12/208 reads (6%) | catalogued as COSV100468002; called by muse, mutect2
- PCLO | c.15255A>G p.R5085= | Silent (SNP) | VAF 35/70 reads (50%) | called by muse, mutect2, varscan2
